Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84C, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84C-01A (Primary Tumor).

[page 1 of 3]
Ref by :

DOB :
Sex : Male

Requested
Collected
Received
Printed

HISTOPATHOLOGY REPORT :

CLINICAL NOTES:

Cervico-medullary mass (intrinsic)

MACROSCOPIC:

'Brain tumour'. The specimen consists of multiple fragments of tan tissue measuring 10x8x2mm. All embedded. (Blocks A and B)

STRUCTURED REPORT FOR TUMOURS OF THE CENTRAL NERVOUS SYSTEM

Adapted from Tumours of the Central Nervous System Structured Reporting Protocol based on WHO classification 2007, 4th Edition. First Edition 2011.

CLINICAL SUMMARY:

Date of Birth/Age:
Sex:
Requesting Clinician:
Treating Clinician(s):
Clinical history on request form:
Ancillary tests requested:
Other clinical history-source:

Cervico-medullary mass (intrinsic)
None

The clinical history was of recurrent vertigo. In summary, the report indicated a central and left-sided medullary intra-axial mass lesion measuring 22x15x22mm. The mass was of high signal on T2 and FLAIR imaging, although essentially isointense to normal brain on T1. There was minimal (if any) enhancement following contrast. MR spectroscopy demonstrated reduced NAA with elevation of choline. The imaging features favoured a low grade glioma. Demyelination was considered far less likely given the considerable mass effect, absence of enhancement and spectroscopy findings. A PET scan may be useful for further investigation.

Recurrent vertigo
Not known
None known
None known
Not known
See above
Contrast enhancement absent.

Presenting symptoms:
Duration of symptoms:
Previous tumour history:
Current and previous treatment:
Family history:
Imaging findings:

Anatomical site of lesion/s:
Intra-axial:
Reason for biopsy:
Clinical diagnosis or differential diagnosis:

Midline and left medulla
Diagnosis
Low grade glioma

MACROSCOPIC SPECIMEN SUMMARY:

Specimen type(s):
Number of specimens:
Dimensions:
Specimen received in:

Multiple fragments of tissue
1
10x8x2mm in aggregate
Formalin

Chondrosarcoma, grade II
940013
66LF
Site Brain, supratentorial
10th
Brain NOS
271.0
271.9
9/10/2013

[page 2 of 3]
Ref by :

DOB :
Sex :

Requested :
Collected :
Received :
Printed :

Triage of fresh tissue:

Fixation:

Amount of unprocessed tissue:

None

Not performed

Formalin

MICROSCOPIC FEATURES:

Microscopic description:

The biopsies are almost entirely tumour tissue. Some neurones are incorporated within one piece. However, there are no adjacent normal tissue to assess for infiltrative pattern of tumour. The tumour is glial. It is moderately cellular. The cells are small with minimal nuclear atypia. The nuclei range from round to ovoid and elongated (spindled). There are abundant glial fibres in the background. One mitosis has been found in all the tissue. There is no necrosis or vascular endothelial proliferation. There is no biphasic pattern, and no Rosenthal fibres or eosinophilic granular bodies. No perivascular lymphocytes are seen.

Proliferation index (Ki67):

20-30%

p53:

Negative

IDH1:

Negative

Mitoses:

<1/10HPF

Distance between tumour and

nearest dural/deep resection margins:

Tumour reaches margins of the biopsies

IMMUNOHISTOCHEMICAL STAINS:

Positive:

Blocks: A & B

Negative:

GFAP

Pending:

NeuN, P53, IDH1

Neurofilament protein

MOLECULAR PATHOLOGY AND OTHER TESTING IF REQUIRED:

FISH 1p 19q and EGFR amplification:

Not indicated

MGMT promoter methylation:

Not indicated

IDH1/IDH2 exon 4 sequencing:

In this instance, this test may assist in diagnosis. As there is no Medicare rebate for this test, an account will be sent to the patient. Therefore, arrangements for testing can only be made with the patient's informed consent. The estimated cost of this test is . If you have the patient's consent and wish to proceed, please fax a signed request form to and the necessary arrangements for testing will be made. Block: A Tumour 100%.

BRAF V660E Mutation analysis and
BRAF exon 15 sequencing:

These tests may also assist in diagnosis in this case. There is also no rebate for this test, which costs up to and requires informed consent.
Block A: Tumour 100%
Block: A Tumour 100%

Clinical trials (with ethics):

Research block requests with ethics
approval when no longer required for
diagnosis:

Block: A

Note: Any further results will be issued as a supplementary report.

LINEAGE:

Glial

OVERALL COMMENT/SUMMARY:

This is a low grade glial neoplasm. The differential diagnosis appears to be between pilocytic astrocytoma WHO Grade 1, and diffuse fibrillary astrocytoma WHO Grade 2. The characteristic biphasic features of

[page 3 of 3]
Ref by

DOB
Sex

Requester
Collected
Received
Printed

pilocytic astrocytoma are not seen. However, on a brief examination, Dr suggests that BRAF genetic analysis might if positive help to confirm the possibility of pilocytic astrocytoma. Astrocytoma WHO Grade 2 is commonly positive for IDH1. IDH-1 immunohistochemistry is negative in this case, so IDH1/IDH2 exon 4 sequencing to detect a rarer mutation would, if positive, help to confirm Grade 2 astrocytoma. A neurofilament stain is being performed to further assess infiltrativeness of the tumour. Dr will examine the case in more detail next week.

DIAGNOSTIC SUMMARY:

Specimen type:
Tumour site and laterality:
WHO 2007 tumour type:

Brain tumour biopsies
Central and left-sided medulla
Differential diagnosis pilocytic astrocytoma WHO Grade 1 vs. diffuse fibrillary astrocytoma WHO Grade 2

ICD-0-3 CODE:

DIAGNOSIS:

MEDULLARY TUMOUR

DIFFERENTIAL DIAGNOSIS PILOCYTIC ASTROCYTOMA WHO GRADE 1 VS. DIFFUSE ASTROCYTOMA WHO GRADE 2. MOLECULAR TESTS MAY BE HELPFUL (SEE TEXT)

Reported by

SUPPLEMENTARY REPORT DATED

Neurofilament protein stain shows large numbers of axons throughout the tumour, in keeping with an infiltrative pattern of growth, and supporting diffuse astrocytoma WHO grade 2.

Surge
Use

Micro

No Act
Cite

Cont
Pat

Sec
Pat

Sec

Cont
Citation

Supp

Text

Tests Completed: Histo. **FINAL REPORT**

Clinical Notes:

Source: NCI Genomic Data Commons file ae158796-7560-4551-be29-d370cfabe3d3 (TCGA-TM-A84C.506E57F2-58E8-44D0-BEBC-CA06F874ABFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).